Somatic mutation profile of tumor specimen TCGA-E1-5305-01A (aliquot TCGA-E1-5305-01A-01D-1893-08) from TCGA case TCGA-E1-5305, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Brain, NOS; Tumor grade: G3; Age at diagnosis: 34.6 years (12,655 days).
Specimen TCGA-E1-5305-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 256e3c53-8390-4091-b7e3-5cde83d159b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E1-5305-10A (Blood Derived Normal), aliquot TCGA-E1-5305-10A-01D-1893-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55cb3d8c-6f33-49ee-a8ab-8d0e94bd6676

The open-access MAF lists 26 somatic variants for this specimen: 24 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 17, In Frame Del 3, Silent 2, Frame Shift Del 2, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 35/82 reads (43%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.809T>C p.F270S | Missense Mutation (SNP) | VAF 20/26 reads (77%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519986, COSV52661272, COSV52676663, COSV52688116; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADCY2 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 53/114 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs769674129, COSV57864636; called by muse, mutect2, varscan2
- AKNAD1 | c.1454A>G p.Y485C | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV62202165; called by muse, mutect2, varscan2
- ALDH1B1 | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 52/148 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as rs1364099198, COSV66620463; called by muse, mutect2, varscan2
- CACNA2D4 | c.1373C>T p.T458M | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373696894; called by muse, mutect2, varscan2
- CDC34 | c.410_412del p.F137del | In Frame Del (DEL) | VAF 37/105 reads (35%) | catalogued as rs749435711; called by mutect2, pindel, varscan2
- CTSC | c.562A>G p.T188A | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs374844651; called by muse, mutect2, varscan2
- DCST2 | c.392T>G p.L131R | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.092); catalogued as COSV55053912; called by muse, mutect2, varscan2
- DNAH1 | c.7882G>A p.V2628I | Missense Mutation (SNP) | VAF 90/220 reads (41%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as rs776553801, COSV70234096; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.995T>C p.L332P | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV58562832; called by muse, mutect2, varscan2
- FXR2 | c.1489del p.R497Gfs*15 | Frame Shift Del (DEL) | VAF 10/84 reads (12%) | catalogued as rs1567747777; called by mutect2, pindel, varscan2
- HNRNPR | c.221_223del p.E74del | In Frame Del (DEL) | VAF 10/92 reads (11%) | catalogued as rs753814756; called by pindel, varscan2
- ITIH2 | c.2467T>C p.S823P | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as COSV64434723; called by muse, mutect2, varscan2
- KBTBD8 | c.713A>G p.K238R | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.019); catalogued as COSV55130774; called by muse, mutect2, varscan2
- KCNB2 | c.1997C>T p.T666M | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.306); catalogued as rs758297898, COSV73050312; called by muse, mutect2, varscan2
- LBP | c.588+2T>A p.X196_splice | Splice Site (SNP) | VAF 8/49 reads (16%) | catalogued as COSV54142683; called by muse, mutect2, varscan2
- LPAR5 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV61692986; called by muse, mutect2
- MROH2B | c.3131A>G p.D1044G | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV68188004; called by muse, mutect2, varscan2
- MYOCD | c.2485G>A p.G829R | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100591739, COSV58509605; called by muse, mutect2, varscan2
- SLC4A7 | c.2147T>C p.V716A | Missense Mutation (SNP) | VAF 68/150 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV55401382; called by muse, mutect2, varscan2
- ATRX | c.6726_6730dup p.H2244Rfs*8 | Frame Shift Ins (INS) | VAF 76/114 reads (67%) | called by mutect2, pindel, varscan2
- COPS2 | c.633_635del p.N211del | In Frame Del (DEL) | VAF 6/62 reads (10%) | called by mutect2, varscan2
- PPP6R2 | c.2215_2216del p.W739Gfs*17 (on ENST00000216061 / NM_001365836.1; = p.W712Gfs*17 on NM_014678.5 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 5/34 reads (15%) | called by pindel, varscan2
- COG3 | c.1995T>C p.N665= | Silent (SNP) | VAF 30/120 reads (25%) | catalogued as COSV63074564; called by muse, mutect2, varscan2
- SRSF3 | c.420T>C p.S140= | Silent (SNP) | VAF 8/242 reads (3%) | catalogued as COSV59671774; called by muse, mutect2
